Surgical pathology report (de-identified scan), TCGA case TCGA-CM-5349, project TCGA-COAD (Colon Adenocarcinoma), tissue source site MSKCC, specimen TCGA-CM-5349-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY REPORT

Clinical Diagnosis & History:

with right colon cancer. No neoadjuvant chemoradiation.

Specimens Submitted:

- 1: SP: Colon, right, colectomy
- 2: SP: Liver biopsy segment three
- 3: SP: Left fallopian tube and ovary
- 4: SP: Right fallopian tube and ovary

DIAGNOSIS:

1. SP: Colon, right, colectomy:

Tumor Type:

Adenocarcinoma

Histologic Grade:

Moderately differentiated

Tumor Location:

Cecum

Tumor Size:

Length is 6.8 cm

Width is 5.8 cm

Maximal thickness is 1.5 cm

Tumor Budding:

Focal

Increased Tumor Infiltrating Lymphocytes:

Absent

Precursor Lesions:

Tubular adenoma

Deepest Tumor Invasion:

Subserosal adipose tissue and/or mesenteric fat

Gross Tumor Perforation:

Not identified

Lymphovascular Invasion:

Not identified

Large Venous Invasion:

Not Identified

Perineural Invasion:

Not identified

Surgical Margins:

Free of tumor

Polyps/Mucosa Dysplasia (away from the carcinoma):

** Continued on next page **

[page 2 of 5]
Not Identified

Non-Neoplastic Bowel:
Unremarkable

Appendix:
involved by adenocarcinoma

Lymph Nodes:
Number with metastasis: 0
Total number examined: 21

Tumor deposits in pericorectal soft tissue:
Not Identified

Tumor Staging (AJCC 7th Edition):
pT3 (Tumor invades through the muscularis propria into
pericorectal tissues)

Lymph Node Stage (AJCC 7th Edition):
N0 (No regional lymph node metastasis)

2. LIVER, SEGMENT III, BIOPSY:
-BENIGN LIVER PARENCHYMA AND VESSELS.
3. FALLOPIAN TUBE AND OVARY, LEFT, RESECTION:
-BENIGN FALLOPIAN TUBE AND OVARY.
4. FALLOPIAN TUBE AND OVARY, RIGHT, RESECTION:
-BENIGN FALLOPIAN TUBE AND OVARY.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF
THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED
THIS REPORT.

1) The specimen is received fresh, labeled "Right colon" and consists of a
segment of terminal ileum, cecum with attached appendix and ascending colon.
The terminal ileum measures 3.5 cm in length and 4 cm in circumference at
the proximal resected margin. The remaining colon measures 28 cm in length
with a circumference of 8 cm at the distal resected margin. The attached
appendix measures 5 cm in length and measures 0.4 cm in diameter at its
distal end; however dilated to 2.5 cm at the proximal end. The appendiceal
and intestinal serosa is pink tan and smooth. Focally hemorrhagic lobulated
yellow tan adipose tissue spans the length of the specimen measuring up to 1
cm in thickness. The specimen is opened to reveal an exophytic mass lesion
measuring 6.8 x 5.8 x 1.5 cm. The mass is centered in the appendiceal
orifice, 3.5 cm from the proximal margin and 23 cm from the distal margin.
Sectioning shows that the tumor invades through muscularis propria to the
serosal surface. The depth of invasion is 1.2 cm grossly. The remaining

** Continued on next page **

[page 3 of 5]
----- Page 3 of 5
mucosa is unremarkable. The attached adipose tissue is thoroughly examined and all identified lymph nodes are submitted. Representative sections of the specimen are submitted for permanent sections and for TPS.

Summary of sections:

P - proximal margin shave
D - distal margin shave
A - appendix from distal to proximal including its orifice involved by the tumor
TCE - tumor (cecum)
TCO - tumor (colon)
TIC- tumor (ileocecal valve)
LN - lymph nodes

2). The specimen is received in formalin, labeled "Liver biopsy segment three" and consists of two tan-brown fragments of soft tissue measuring 0.8x 0.3 x 0.2 cm and 2.0 x 1.0 x 0.7 cm. The larger wedge shaped fragment is inked at the surgical margin and bisected. The entire specimen is submitted.

Summary of sections:

L--larger tissue
S--smaller tissue

3). The specimen is received in formalin, labeled "Left fallopian tube and ovary" and consists of a fallopian tube with attached ovary. The fallopian tube measures 4.5 cm in length and averages 0.5 cm in diameter. The external surface of the tube is pink tan and smooth with a normal fimbriated end, multiple paratubal cysts are identified averaging 0.1 cm. Cut section through the tube reveals a pinpoint lumen. The attached ovary weighs 2.5 g and measures 2.5 x 1.0 x 0.8 cm. The external surface is yellow and smooth. Cut section through the ovary reveals yellow-white ovarian stroma. No discrete lesions are grossly identified. Representative sections are submitted.

Summary of sections:

F - fallopian tube
O - ovary

4). The specimen is received in formalin, labeled "Right fallopian tube and ovary" and consists of a fallopian tube with attached ovary. The fallopian tube measures 4.5 cm in length and averages 0.5 cm in diameter. The external surface of the tube is pink tan and smooth with a normal fimbriated end. Paratubal cysts are identified averaging 0.2 cm. Cut section through the tube reveals a pinpoint lumen. The attached ovary weighs 2.5 g and measures 3.1 x 1.5 x 1.3 cm. The external surface is yellow and smooth. Cut section through the ovary reveals yellow-white ovarian stroma. Representative sections are submitted.

** Continued on next page **

[page 4 of 5]
Summary of sections:

F - fallopian tube
O - ovary

Summary of Sections:

Part 1: SP: Colon, right, colectomy

Block	Sect.	Site	PCs
4		a	7
2		d	3
7		LN	21
1		p	1
2		tce	2
2		tco	2
2		tic	2

Part 2: SP: Liver biopsy segment three

Block	Sect.	Site	PCs
1		L	2
1		S	1

Part 3: SP: Left fallopian tube and ovary

Block	Sect.	Site	PCs
2		F	3
2		O	2

Part 4: SP: Right fallopian tube and ovary

Block	Sect.	Site	PCs
2		F	4
2		O	3

Addendum Diagnosis

THE IMMUNOHISTOCHEMICAL STAINING FOR THE TESTED DNA MISMATCH REPAIR PROTEINS (MLH1, MSH2, MSH6 AND PMS2) IS RETAINED IN THE TUMOR.

** Continued on next page **

[page 5 of 5]
** End of Report **

Source: NCI Genomic Data Commons file b7456c51-a0ea-4de0-b4c1-2842cba9b722 (TCGA-CM-5349.F4491D68-EC4B-45D7-BAB8-CF4ED1FFAF62.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).